Somatic mutation profile of tumor specimen TARGET-20-PASNKC-09A (aliquot TARGET-20-PASNKC-09A-01D) from TARGET case TARGET-20-PASNKC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,535 days).
Specimen TARGET-20-PASNKC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e99bed4-0df9-4e24-914f-1837d09ae5e0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASNKC-14A (Bone Marrow Normal), aliquot TARGET-20-PASNKC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d5f8004-4ffa-4db9-8067-4970efd938a2

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF7IP | c.1690A>G p.N564D | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.415); catalogued as rs1239002057; called by muse, mutect2, varscan2
- FLT3 | c.1992G>A p.M664I | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV54046071, COSV54047442, COSV54051809; called by muse, mutect2, varscan2
- NONO | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV52139060; called by muse, mutect2, varscan2
- FLT3 | c.1993A>T p.M665L | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
